Somatic mutation profile of tumor specimen MP2PRT-PATVSK-TMP1-A (aliquot MP2PRT-PATVSK-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PATVSK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,532 days).
Specimen MP2PRT-PATVSK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df5d430b-731a-4499-a099-85cd2d21f7ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATVSK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATVSK-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7401139c-54a4-405a-98f6-2d9844ca715b

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK3 | c.3124T>A p.L1042I (on ENST00000280772 / NM_001320874.2; = p.L176I on NM_001149.3) | Missense Mutation (SNP) | VAF 13/299 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55043245; called by muse, mutect2
- GPRC5D | c.68G>C p.G23A | Missense Mutation (SNP) | VAF 123/301 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs939696663; called by muse, mutect2
- KRT85 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 184/400 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs1471973724, COSV57736445; called by muse, mutect2, varscan2
- LRP3 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 201/482 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as rs763835668, COSV53502714; called by muse, mutect2, varscan2
- TRPS1 | c.992A>C p.K331T (on ENST00000220888 / NM_001330599.2; = p.K344T on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/289 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1446106207; called by muse, mutect2, varscan2
- TSC22D3 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 223/577 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.356); catalogued as rs944324427; called by muse, mutect2, varscan2
- APOD | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 80/213 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- LMX1A | c.281G>A p.C94Y | Missense Mutation (SNP) | VAF 79/179 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- GABRR2 | c.768G>A p.T256= | Silent (SNP) | VAF 83/226 reads (37%) | catalogued as rs146287342; called by muse, mutect2, varscan2
- MRPL44 | c.735G>A p.L245= | Silent (SNP) | VAF 63/202 reads (31%) | catalogued as COSV51314593; called by muse, mutect2, varscan2
- STAB2 | c.3507C>T p.A1169= | Silent (SNP) | VAF 77/221 reads (35%) | catalogued as rs756891521, COSV66346812; called by muse, mutect2, varscan2
